Somatic mutation profile of tumor specimen MP2PRT-PASNHW-TMP1-A (aliquot MP2PRT-PASNHW-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASNHW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,091 days).
Specimen MP2PRT-PASNHW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f83c21cd-836b-4181-87dd-9fc199444d5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASNHW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASNHW-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27dd446b-8d93-4a12-ab5a-5bbbbe20e62a

The open-access MAF lists 117 somatic variants for this specimen: 77 protein-altering or splice-affecting, 37 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 37, Nonsense Mutation 7, Intron 3, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.4324G>C p.E1442Q | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs759663539; called by muse, mutect2
- ADPRHL1 | c.5065C>T p.R1689W | Missense Mutation (SNP) | VAF 96/475 reads (20%) | SIFT tolerated, low confidence (0.13); catalogued as rs1472722572; called by muse, varscan2
- ARHGAP30 | c.1083G>C p.E361D | Missense Mutation (SNP) | VAF 29/396 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.218); catalogued as COSV63515776; called by muse, mutect2
- CHD2 | c.2443C>G p.Q815E | Missense Mutation (SNP) | VAF 101/320 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101244926; called by muse, mutect2, varscan2
- DNAI2 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 21/331 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1159172844; called by muse, mutect2
- DUT | c.93G>C p.Q31H | Missense Mutation (SNP) | VAF 25/545 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV58664030; called by muse, mutect2
- GRHL1 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.196); catalogued as COSV61410387; called by muse, mutect2, varscan2
- MAG | c.1035C>G p.I345M | Missense Mutation (SNP) | VAF 129/343 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100727596; called by muse, mutect2, varscan2
- MEDAG | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV100995237; called by muse, mutect2, varscan2
- MEN1 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 141/399 reads (35%) | catalogued as COSV53644198; called by muse, mutect2, varscan2
- MNDA | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 93/278 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV100933438; called by muse, mutect2, varscan2
- NEBL | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV65799748; called by muse, mutect2
- OR8K3 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 15/342 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs200418517, COSV57130852; called by muse, mutect2
- POTEG | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 132/1238 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs770223421; called by muse, mutect2, varscan2
- POU4F3 | c.779G>C p.R260P | Missense Mutation (SNP) | VAF 117/296 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57942285; called by muse, varscan2
- RASSF8 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140972036; called by muse, mutect2, varscan2
- REPIN1 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 159/427 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV68292371; called by muse, mutect2, varscan2
- RNF128 | c.550C>T p.Q184* (on ENST00000255499 / NM_194463.2; = p.Q158* on NM_024539.3) | Nonsense Mutation (SNP) | VAF 23/286 reads (8%) | catalogued as COSV55250212; called by muse, mutect2
- SASH1 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.106); catalogued as rs759775810; called by muse, mutect2
- SIKE1 | c.273G>C p.W91C | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50258836; called by muse, mutect2, varscan2
- SPEF2 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.214); catalogued as COSV61552532; called by muse, mutect2
- SPOCK1 | c.639G>T p.W213C | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs751766861; called by muse, mutect2, varscan2
- SPTBN2 | c.6493G>A p.E2165K | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs372101504; called by muse, mutect2
- SPTBN2 | c.3431G>A p.R1144Q | Missense Mutation (SNP) | VAF 27/478 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.094); catalogued as rs558572111, COSV59455248; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- TRHDE | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 32/596 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1427058493; called by muse, mutect2
- ZBTB24 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 99/287 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs761036277; called by muse, mutect2, varscan2
- ZNF689 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 100/296 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.14); catalogued as rs769345382, COSV54907975; called by muse, mutect2, varscan2
- ZNF71 | c.1158C>G p.I386M | Missense Mutation (SNP) | VAF 149/418 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.245); catalogued as COSV60148860, COSV60149227; called by muse, mutect2, varscan2
- ZNF721 | c.1694G>C p.R565T (on ENST00000338977; = p.R577T on NM_133474.4) | Missense Mutation (SNP) | VAF 125/356 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as COSV59091796, COSV59092068; called by muse, varscan2
- CADPS2 | c.3233C>T p.S1078F | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- CFHR5 | c.862C>G p.Q288E | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2
- CNNM4 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- COA6 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 17/275 reads (6%) | called by muse, mutect2
- COL24A1 | c.3865C>A p.P1289T | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- COPB1 | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COPE | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 82/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CPXCR1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.181); called by muse, mutect2
- CYP2E1 | c.1195G>C p.D399H | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2
- DBF4 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FOXD3 | c.1073C>G p.A358G | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by muse, mutect2
- FYCO1 | c.3475G>C p.E1159Q | Missense Mutation (SNP) | VAF 126/352 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GTPBP1 | c.1485G>C p.E495D | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.261); called by muse, mutect2
- HERC1 | c.3152G>C p.R1051T | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- HSCB | c.126G>C p.W42C | Missense Mutation (SNP) | VAF 149/377 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGB5 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 12/325 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LIMCH1 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 129/365 reads (35%) | called by muse, mutect2, varscan2
- LY75 | c.3688G>C p.E1230Q | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- MFSD11 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MPDZ | c.2899C>G p.L967V | Missense Mutation (SNP) | VAF 93/276 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NBEA | c.5303C>A p.P1768Q | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- NEIL1 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 28/526 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- NPIPA1 | c.968C>G p.S323* | Nonsense Mutation (SNP) | VAF 121/923 reads (13%) | called by muse, mutect2, varscan2
- OTUD7B | c.1168C>A p.H390N | Missense Mutation (SNP) | VAF 13/287 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PGAP4 | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 123/345 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- PNLDC1 | c.804C>G p.F268L | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SHROOM4 | c.4376C>G p.S1459C | Missense Mutation (SNP) | VAF 30/515 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC22A4 | c.555C>G p.F185L | Missense Mutation (SNP) | VAF 85/291 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SSX1 | c.27G>C p.K9N | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); called by muse, mutect2
- STXBP5 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TAOK1 | c.2366_2367insGCCTAGGCCG p.L790Pfs*6 | Frame Shift Ins (INS) | VAF 22/226 reads (10%) | called by mutect2, pindel
- TARS3 | c.2037G>A p.M679I | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- TLCD4 | c.278C>A p.A93D | Missense Mutation (SNP) | VAF 17/289 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- TNK1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNK1 | c.585G>A p.V195= | Splice Region (SNP) | VAF 19/353 reads (5%) | called by muse, mutect2
- TRPC4 | c.2927G>A p.R976K (on ENST00000379705 / NM_016179.4; = p.R981K on NM_003306.3) | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TUT1 | c.1088C>G p.S363C | Missense Mutation (SNP) | VAF 103/315 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- UBA2 | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC80 | c.8689G>A p.E2897K | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- VPS13C | c.6941C>G p.S2314C (on ENST00000644861 / NM_020821.3; = p.S2271C on NM_017684.5) | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- WDFY4 | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 13/350 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2
- WDR13 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.522); called by muse, mutect2
- WLS | c.1259T>C p.V420A | Missense Mutation (SNP) | VAF 120/243 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3HC1 | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 15/323 reads (5%) | called by muse, mutect2
- ZNF555 | c.563G>C p.R188T | Missense Mutation (SNP) | VAF 115/312 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF610 | c.1275G>C p.E425D | Missense Mutation (SNP) | VAF 124/303 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF770 | c.632C>G p.S211* | Nonsense Mutation (SNP) | VAF 79/209 reads (38%) | called by muse, mutect2, varscan2
- ZSWIM5 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AASS | c.870C>G p.R290= | Silent (SNP) | VAF 29/211 reads (14%) | called by muse, mutect2, varscan2
- ANKRD13B | c.1269C>T p.I423= | Silent (SNP) | VAF 102/235 reads (43%) | called by muse, mutect2, varscan2
- ATP13A3 | c.1686G>C p.L562= | Silent (SNP) | VAF 58/179 reads (32%) | called by muse, mutect2, varscan2
- CACNA1A | c.6453C>G p.P2151= | Silent (SNP) | VAF 26/478 reads (5%) | called by muse, mutect2
- CHRNB1 | c.927C>T p.I309= | Silent (SNP) | VAF 15/367 reads (4%) | called by muse, mutect2
- COL22A1 | c.4152G>A p.G1384= | Silent (SNP) | VAF 16/416 reads (4%) | catalogued as COSV57324780; called by muse, mutect2
- CUBN | c.3777G>A p.L1259= | Silent (SNP) | VAF 15/341 reads (4%) | called by muse, mutect2
- DGKZ | c.1518C>G p.L506= (on ENST00000454345 / NM_001105540.2; = p.L318= on NM_003646.4) | Silent (SNP) | VAF 102/265 reads (38%) | called by muse, mutect2, varscan2
- DIAPH2 | c.531G>A p.E177= | Silent (SNP) | VAF 75/222 reads (34%) | called by muse, mutect2, varscan2
- FAM104B | c.312C>T p.L104= | Silent (SNP) | VAF 60/217 reads (28%) | catalogued as COSV59775993; called by muse, mutect2, varscan2
- FMO2 | c.975C>T p.I325= | Silent (SNP) | VAF 14/362 reads (4%) | called by muse, mutect2
- GRIN2D | c.1296C>G p.L432= | Silent (SNP) | VAF 156/453 reads (34%) | called by muse, mutect2, varscan2
- GRIN2D | c.1944G>A p.E648= | Silent (SNP) | VAF 77/230 reads (33%) | called by muse, mutect2, varscan2
- GSK3A | c.189G>A p.S63= | Silent (SNP) | VAF 22/588 reads (4%) | called by muse, mutect2
- IL1RL1 | c.603G>A p.T201= | Silent (SNP) | VAF 55/148 reads (37%) | catalogued as rs201621624, COSV52119058, COSV99293858; called by muse, mutect2, varscan2
- KCTD13 | c.264G>C p.R88= | Silent (SNP) | VAF 54/178 reads (30%) | called by muse, mutect2, varscan2
- MASP1 | c.2091G>A p.V697= | Silent (SNP) | VAF 14/216 reads (6%) | catalogued as COSV61826088; called by muse, mutect2
- MYH11 | c.2307C>T p.F769= | Silent (SNP) | VAF 25/452 reads (6%) | catalogued as rs1282852123, COSV55561668; called by muse, mutect2
- N4BP2L2 | c.1590G>A p.Q530= | Silent (SNP) | VAF 75/200 reads (38%) | catalogued as rs779994962; called by muse, mutect2, varscan2
- OIP5 | c.150C>A p.L50= | Silent (SNP) | VAF 14/362 reads (4%) | catalogued as COSV99530833; called by muse, mutect2
- OR4A8 | c.576C>T p.F192= | Silent (SNP) | VAF 92/245 reads (38%) | catalogued as rs756899085; called by muse, mutect2, varscan2
- PSMD1 | c.234G>A p.L78= | Silent (SNP) | VAF 10/319 reads (3%) | called by muse, mutect2
- RFX3 | c.1107G>A p.V369= | Silent (SNP) | VAF 84/226 reads (37%) | called by muse, mutect2, varscan2
- SLC25A14 | c.141C>T p.G47= | Silent (SNP) | VAF 99/279 reads (35%) | catalogued as rs758053843, COSV54418187; called by muse, mutect2, varscan2
- SLC49A3 | c.1638G>A p.P546= (on ENST00000404286 / NM_001294341.2; = p.P545= on NM_032219.4) | Silent (SNP) | VAF 147/378 reads (39%) | catalogued as rs548056487; called by muse, mutect2, varscan2
- SRRT | c.1128C>T p.S376= | Silent (SNP) | VAF 82/212 reads (39%) | catalogued as rs138346691; called by muse, varscan2
- TMEM17 | c.315G>A p.E105= | Silent (SNP) | VAF 41/119 reads (34%) | called by muse, mutect2, varscan2
- TNRC6C | c.504G>A p.Q168= | Silent (SNP) | VAF 15/368 reads (4%) | catalogued as rs1403447237; called by muse, mutect2
- TRAF3IP2 | c.1464G>A p.E488= | Silent (SNP) | VAF 96/251 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.58659C>T p.L19553= (on ENST00000591111; = p.L12129= on NM_003319.4) | Silent (SNP) | VAF 113/329 reads (34%) | catalogued as COSV60260133; called by muse, mutect2, varscan2
- TUBB4A | c.903G>A p.A301= | Silent (SNP) | VAF 152/318 reads (48%) | catalogued as rs767479203, COSV51163766; called by muse, mutect2, varscan2
- TUT1 | c.1107C>T p.V369= | Silent (SNP) | VAF 93/278 reads (33%) | called by muse, varscan2
- VCAN | c.984T>C p.F328= | Silent (SNP) | VAF 24/408 reads (6%) | called by muse, mutect2
- VSIG10L | c.882G>A p.T294= | Silent (SNP) | VAF 82/196 reads (42%) | catalogued as rs764549321; called by muse, mutect2, varscan2
- ZBED3 | c.60G>A p.A20= | Silent (SNP) | VAF 23/491 reads (5%) | called by muse, mutect2
- ZBTB48 | c.426C>T p.V142= | Silent (SNP) | VAF 117/284 reads (41%) | called by muse, mutect2, varscan2
- ZNF418 | c.483C>T p.F161= | Silent (SNP) | VAF 19/417 reads (5%) | catalogued as rs1475281583; called by muse, mutect2
- ACP6 | c.781-64G>A | Intron (SNP) | VAF 15/359 reads (4%) | called by muse, mutect2
- BBIP1 | c.38-6090G>A | Intron (SNP) | VAF 60/171 reads (35%) | catalogued as rs753378493; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+36256G>C | Intron (SNP) | VAF 56/169 reads (33%) | called by muse, mutect2, varscan2
